Somatic mutation profile of tumor specimen TARGET-10-PANTXA-09A (aliquot TARGET-10-PANTXA-09A-01D) from TARGET case TARGET-10-PANTXA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,357 days).
Specimen TARGET-10-PANTXA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cad5b295-80fa-4362-951c-400e05d31349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTXA-14A (Bone Marrow Normal), aliquot TARGET-10-PANTXA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d0e394d-b3f8-4c3e-82a5-d79386788897

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- RASSF9 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as rs1053694318, COSV63432565; called by muse, mutect2, varscan2
- GPATCH8 | c.3498G>A p.L1166= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV59193272; called by muse, mutect2, varscan2
- KCNN3 | c.1278C>T p.S426= | Silent (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- ZNF462 | c.3477G>A p.G1159= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1320524541; called by muse, mutect2, varscan2
- ADAM29 | c.*45G>A | 3'UTR (SNP) | VAF 14/100 reads (14%) | catalogued as rs1359984729; called by muse, mutect2, varscan2
- FCRL6 | c.-3C>T | 5'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
